National Lung Screening Trial (NLST) participant 106662 — screening results and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 60 years; Gender: male; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; no CT screening exam record exists for this participant — in this public subset that is the pattern of the chest-radiography arm: every CT screen with a result has an exam record, and the subset has no trial-arm field)
- T0 (day 0): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer.
- T1 (day 335): Positive, no significant change: stable abnormalities potentially related to lung cancer, unchanged since the prior screening exam. Isolation read, before comparison with prior images: negative screen, no significant abnormalities.
- T2 (day 680): Positive, other. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality).

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer occurred after the screening years; study year of the first confirmed lung cancer: T5; the diagnosis is not linked to a positive screen by the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 2,051, study year T5. Site: main bronchus (ICD-O-3 C34.0), determined from histology. Primary tumour location: right hilum. Histology: small cell carcinoma, NOS (ICD-O-3 8041/3). Grade: cannot be assessed (GX). Tumour size on pathology: 100 mm. AJCC 6th edition staging: stage IV (best stage, from clinical TNM); clinical T4 N2 M1 (stage IV). AJCC 7th edition staging: stage IV; clinical T3 N2 M1b. VALCSG stage (the small-cell staging system; ACRIN recorded it for all its lung cancers): extensive.

Follow-up
Last known free of lung cancer: day 1,834.
